Somatic mutation profile of tumor specimen MP2PRT-PATIXA-TMP1-A (aliquot MP2PRT-PATIXA-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATIXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,948 days).
Specimen MP2PRT-PATIXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb866953-d448-43b7-80f0-51df7387e845.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIXA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIXA-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aac5dc2c-326c-4c52-bb3c-1c5b83cb6c3c

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/314 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 45/385 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 182/379 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs373407780, COSV55047992; called by muse, varscan2
- PTGIR | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs200100794; called by muse, mutect2, varscan2
- RASGRP4 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 117/451 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs374569775; called by muse, mutect2, varscan2
- CHL1 | c.489C>A p.H163Q | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF13 | c.203dup p.L68Ffs*3 | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | called by mutect2, pindel, varscan2
- CNNM1 | c.1464C>T p.D488= | Silent (SNP) | VAF 162/372 reads (44%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.1209C>T p.G403= | Silent (SNP) | VAF 300/582 reads (52%) | catalogued as rs1164167692, COSV61749345; called by muse, mutect2, varscan2
- TLL2 | c.1131C>T p.C377= | Silent (SNP) | VAF 75/355 reads (21%) | catalogued as rs745772605, COSV63575157; called by muse, mutect2, varscan2
- NHS | c.853-2084G>A | Intron (SNP) | VAF 77/449 reads (17%) | catalogued as rs1490932762; called by muse, mutect2, varscan2
